Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABJ4, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABJ4-TTP2-A (Primary Tumor).

[page 1 of 2]
Material: A) Right lung, upper lobe, removal
B) Lymph node station 10R, removal
C) Right paratracheal lymph node, removal

Macro Description: A) Pulmonary lobe. 17x10x2.5 cm site of 4.5 cm brownish neoformation with polycyclic margins, 3.5 cm from the bronchial resection margin. 6 peribronchial lymph nodes are isolated. Remaining parenchyma without important macroscopic alterations.
B) A fragment of adipose tissue, 5 cm main axis, from which 6 lymph nodes are isolated.
C) Lymph node, 0.6 cm main axis.

Micro Description: A) Well differentiated pulmonary adenocarcinoma (G1), mixed type (papillary and bronchioloalveolar).

No evidence of peritumoral neoplastic angioinvasiveness.

Bronchial surgery resection margin and visceral pleura free of neoplasia.

Non-specific reactive lymphonoditis with histiocytosis of sinuses and anthracosis

B, C) Non-specific reactive lymphonoditis with histiocytosis of sinuses and anthracosis.

Stage: T2N0 G1

Report 2:

Date Report 2:

Material 2:

Macro Description 2:

Notes: missing (report printed from computer).

ICDO Code: 82553

ICDO Description: Adenocarcinoma with mixed subtypes

Status: OK

Other Info:

ICD-0-3

adenocarcinoma, with mixed subtypes 8255/3

Site: (R) Lung, upper lobe C34.1

ICD-10

C34.11

hw
2/9/16

[page 2 of 2]
Material: A) Right lung, upper lobe, removal

B) Lymph node station 10R, removal

C) Right paratracheal lymph node, removal

Macro Description: A) Pulmonary lobe. 17x10x2.5 cm site of 4.5 cm brownish neoformation with polycyclic margins, 3.5 cm from the bronchial resection margin. 6 peribronchial lymph nodes are isolated. Remaining parenchyma without important macroscopic alterations.

B) A fragm

Micro Description: A) Well differentiated pulmonary adenocarcinoma (G1), mixed type (papillary and bronchioloalveolar).

No evidence of peritumoral neoplastic angioinvasiveness.

Bronchial surgery resection margin and visceral pleura free of neoplasia.

Non-specific reacti

Virtual Microscope: AD CA, papill. Well diff.

Real Microscope: adenocarcinoma papillary, well diff Additional notes: ph! Tumor

Slide Quality: 3- poor nucleous details

Stage: T2N0 G1

cT	cN	cM	cStage	cGrading
2	0	0	IB	X

pT	pN	pM	pStage	pGrading
2	0	0	IB	1

Report 2:

Report Date 2:

Criteria	hw 2/9/16	Yes	No
Dual/Synchronous Primary	Noted		

Source: NCI Genomic Data Commons file 98a9565c-8d01-403f-b3e7-1284802048f1 (CDDP-ABJ4-TTP2.E0E50A46-7850-4783-A42C-4A888BE5CEB4.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).